Surgical pathology report (de-identified scan), TCGA case TCGA-QU-A6IP, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Harvard Beth Israel, specimen TCGA-QU-A6IP-01A (Primary Tumor).

[page 1 of 3]
Pathology Examination

Name	Birthdate	Age	Sex	Pathology #
[REDACTED]	[REDACTED]		Male	[REDACTED]

Report to:
Gross Description by:

SPECIMEN SUBMITTED: PROSTATE, LEFT/RIGHT LYMPH NODE (RT. & LT. PELVIC LYMPH NODES).

Procedure date Tissue received Report Date Diagnosed by

Previous biopsies: Consult slides referred to

DIAGNOSIS:

1. Left lymph node (A): Single lymph node, no malignancy identified.
2. Right lymph node (B): Single lymph node, no malignancy identified.
3. Prostate and seminal vesicles (C-O): Adenocarcinoma involving right lobe; see synopsis report.

Prostate Gland: Radical prostatectomy Synopsis**MICROSCOPIC**

Histologic Type: Adenocarcinoma.

Histologic Grade -- Gleason Pattern

Primary pattern: Grade 3.

Secondary pattern: Grade 3.

Total Gleason Score: 6.

Tumor quantitation

Proportion (percent) of prostate involved by tumor: 5%.

	# Positive Slides	Total Slides
Left	0	3
Left apex	0	2
Right	1	3
Right apex	0	2

EXTENT OF INVASION

CLCF ICD-O-3
Adenocarcinoma acinar
path 8/40/3
Adenocarcinoma NOS
8/40/3
Site Prostate NOS
C61.9

[page 2 of 3]
Primary Tumor: pT2a: Unilateral, involving one-half of 1 side ("lobe ") or less.

Regional Lymph Nodes: pN0: No regional lymph node metastasis.

Lymph Nodes

Number examined: 2.

Number involved: 0.

Margins:

Margins uninvolved by invasive carcinoma.

Extraprostatic extension: Absent.

Seminal vesicle invasion (invasion of muscular wall required): Absent.

Perineural invasion: Present.

Comments: Small focus of probable carcinoma in right mid (H) as well.

Clinical: Prostate cancer.

Gross: The specimen is received fresh in three parts all labeled [REDACTED]

Part 1 is labeled "left pelvic lymph node pocket" and consists of a piece of adipose tissue measuring 3.5 x 3 x 1.5 cm. The specimen is examined for lymph nodes. One lymph node measuring 0.2 cm is identified. The lymph node is entirely submitted in cassette A.

Part 2 is labeled "right pelvic lymph node pocket" and consists of fragments of adipose tissue measuring 4.5 x 3.5 x 1.5 cm in aggregate. The specimen is examined for lymph node. One lymph node is identified measuring 1.5 cm. The lymph node is entirely submitted in cassette B.

Part 3 is labeled "prostate and seminal vesicles" and consists of a prostatectomy specimen weighing 51 grams and measuring 5.5 x 5 x 3.5 cm. The right seminal vesicle measures 2.5 x 1.5 x 0.5 cm. The right vas deferens measures 0.5 cm in length and 0.5 cm in diameter. The left seminal vesicle measures 2.5 x 1.5 x 0.5 cm. The left vas deferens measures 1 cm in length and 0.5 cm in diameter. Prostatic capsule is grossly unremarkable. The specimen is inked as follows: right = black, left = blue. The urethral (apical) and the lateral margins are shaved up and the specimen is serially sectioned to reveal a nodular pattern of the prostatic parenchyma. No discrete lesions are grossly identified. The specimen is represented as follows: C-D = right apical resection margin, coned and serially sectioned, E-F = left apical resection margin, coned and serially sectioned. G-I = right apex, mid and base respectively, J-L = left apex, mid and base, respectively., M = bladder resection margin shave, N = right seminal vesicle, O = left seminal vesicle.

By his/her signature above, the senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimens(s) and rendered or confirmed the diagnosis(es) related thereto.

Immunohistochemistry test(s), if applicable, were developed and their performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined

[page 3 of 3]
that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA - 88) as qualified to perform high complexity clinical laboratory testing.

Criteria:	6/11/13	Yes	No

Source: NCI Genomic Data Commons file cb527938-09cf-4071-bc30-5f8c544083e1 (TCGA-QU-A6IP.D1E73097-6F07-4B1E-8914-074FA037CB85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).